Somatic mutation profile of tumor specimen TCGA-KM-8440-01A (aliquot TCGA-KM-8440-01A-11D-2310-10) from TCGA case TCGA-KM-8440, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 37.9 years (13,860 days).
Specimen TCGA-KM-8440-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b202b314-b71c-4433-a98d-af952982add5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KM-8440-10A (Blood Derived Normal), aliquot TCGA-KM-8440-10A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbfee472-066f-4d97-acb5-8a69b32f55a7

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSCAM | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV68638198, COSV68657536; called by muse, mutect2, varscan2
- FOXO1 | c.1272T>A p.Y424* | Nonsense Mutation (SNP) | VAF 64/88 reads (73%) | catalogued as COSV104427929; called by muse, mutect2, varscan2
- H2AZ1 | c.122C>A p.T41K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV99597628; called by muse, mutect2
- KMT2D | c.5821A>G p.M1941V | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs372271746; called by muse, mutect2, varscan2
- SMCO2 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs1207526498; called by muse, mutect2, varscan2
- VWCE | c.2758G>A p.V920M | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs550040653, COSV57110958; called by muse, mutect2, varscan2
- DDX24 | c.1948G>T p.G650C | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARF1 | c.4480G>T p.V1494L | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NUDT9 | c.1048T>C p.L350= | Silent (SNP) | VAF 16/76 reads (21%) | called by mutect2, varscan2
